CCDI case PBCFPY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4fc1ad0f-b29e-49a6-89b0-8de782563bcd

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,486 days).

Biospecimens (2 samples)
- Sample 0DQVIE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQVIZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
